Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RF, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RF-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED] F) Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:
Anterior mediastinal mass.

Specimens Submitted:
1: Anterior mediastinal mass

DIAGNOSIS:

1. Anterior mediastinum; excision:
- Thymoma, WHO type A, see note.
- There is microscopic invasion of capsule.
- Tumor measures 2.2 x 2.2 x 1.5 cm.
- Tumor is not seen at the surgical margin.
- Adjacent thymus shows involutional changes.

Note: Immunohistochemical stains show that the tumor cells are positive for AE1/AE3, with CD3 and TdT labeling intermixed lymphocytes.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1. The specimen is received fresh, labeled "anterior mediastinal mass" and consists of a 6.5 x 3.5 x 2 cm unoriented previously incised fragment of yellow soft tissue weighing 21 g. The specimen is inked black. Serial sections reveal a well circumscribed fleshy yellow solid tissue mass measuring 2.2 x 2.2 x 1.5 cm. The mass is covered by a membrane. A portion of the mass is submitted for TPS. The remaining lesion is entirely submitted.

Summary of sections:
M mass
F surrounding fat

** Continued on next page **

ICD-O-3
Thymoma, type A, malignant
8581/3
Site Anterior, mediastinum
(38.)

JW 3/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient:

MRN:

Account #:

Accession #:

Physician:

Service:

Date of Report:

Page 2 of 2

Summary of Sections:

Part 1: Anterior mediastinal mass

Block	Sect.	Site	PCs
2		f	2
6		m	6

** End of Report **

Source: NCI Genomic Data Commons file 3c28946b-c745-42cf-9ed5-cdd7a67d4fee (TCGA-XM-A8RF.B6435C23-20B0-48EE-8EB0-6E702F784DAA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).